Surgical pathology report (de-identified scan), TCGA case TCGA-2G-AAIE, project TCGA-TGCT (Testicular Germ Cell Tumors), specimen TCGA-2G-AAIE-01A (Primary Tumor).

Department of Pathology

Direct dial

Mobile:

Internal postal address

E-mail

Date

Concerning

Postal address

Street address

Summary pathology report

Right orchidectomy; seminoma; diameter 5.0 cm; focal angio-invasion present; no invasion in rete testis; no invasion of tunica albuginea; epididymis free of tumor; surgical margin of spermatic cord free of tumor.

Date of procurement (= date of orchidectomy):

ICD-0-3

Seminoma NOS 9061/3

Site: R Testis NOS C62.9

7/3/14

pathologist

professor of pathology

Source: NCI Genomic Data Commons file 9b1b700a-b6d4-487f-bf6c-e78b8f44af11 (TCGA-2G-AAIE-01A.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).